Somatic mutation profile of tumor specimen TCGA-A3-3331-01A (aliquot TCGA-A3-3331-01A-01W-0886-08) from TCGA case TCGA-A3-3331, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-A3-3331-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3734afc-c52c-4296-99fb-a3d4418196d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3331-11A (Solid Tissue Normal), aliquot TCGA-A3-3331-11A-01W-0886-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85290272-cc01-4162-88b7-f0c0c1c246f3

The open-access MAF lists 82 somatic variants for this specimen: 62 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Frame Shift Del 4, Nonsense Mutation 3, Nonstop Mutation 1, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 58/114 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56544026, COSV56544770; called by muse, mutect2, varscan2
- AADAT | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61787513; called by muse, mutect2
- CACNA1C | c.6547G>T p.E2183* (on ENST00000399634 / NM_001167625.1; = p.E2112* on NM_000719.7) | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59758289; called by muse, mutect2, varscan2
- CCDC63 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV57527780, COSV57527882; called by muse, mutect2, varscan2
- CD63 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1482247479, COSV57676130; called by muse, mutect2, varscan2
- COL4A5 | c.4409C>G p.T1470R | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60367721; called by muse, mutect2
- CSF3R | c.922C>G p.R308G | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM146259, COSV58969464; called by muse, mutect2, varscan2
- DISP3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99607340; called by muse, mutect2, varscan2
- FLG2 | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 60/640 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs767452601; called by muse, mutect2
- HADHB | c.151A>T p.I51L | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58544878; called by muse, mutect2, varscan2
- IGBP1P2 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs767379178; called by muse, mutect2, varscan2
- MAGEB6 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs757316619, COSV100983856; called by muse, mutect2, varscan2
- NFATC3 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs754716812; called by muse, mutect2, varscan2
- NLRP8 | c.2138G>C p.S713T | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); catalogued as COSV52593529; called by muse, mutect2, varscan2
- OGFOD2 | c.529G>A p.G177R (on ENST00000228922 / NM_001304833.1; = p.G117R on NM_024623.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771872644, COSV54895998; called by muse, varscan2
- OR4C15 | c.966A>T p.K322N (on ENST00000314644; = p.K268N on NM_001001920.2) | Missense Mutation (SNP) | VAF 51/674 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs769839208; called by muse, mutect2
- PATL1 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.123); catalogued as rs375423950; called by muse, mutect2, varscan2
- PBRM1 | c.2657T>G p.L886R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56271681; called by muse, mutect2, varscan2
- PCDHA13 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV56530826; called by muse, mutect2, varscan2
- SLCO1C1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV56869168; called by muse, mutect2, varscan2
- TEKT5 | c.1436del p.P479Rfs*? | Frame Shift Del (DEL) | VAF 10/122 reads (8%) | catalogued as rs1422956059; called by mutect2, pindel
- TIAF1 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as rs1360313360; called by muse, mutect2
- TMCO3 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.882); catalogued as rs749809127; called by muse, varscan2
- ZC4H2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62004558, COSV62007012; called by muse, mutect2
- ANKRD17 | c.422A>C p.D141A | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CASP8 | c.442A>G p.K148E (on ENST00000432109 / NM_033355.3; = p.K180E on NM_001228.4) | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CKAP5 | c.3468A>T p.K1156N | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CNGA1 | c.1880A>T p.E627V | Missense Mutation (SNP) | VAF 136/424 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CSMD3 | c.2519_2528delinsTT p.P840Lfs*19 (on ENST00000297405 / NM_001363185.1; = p.P736Lfs*19 on NM_052900.3) | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | called by pindel, varscan2*
- CUX2 | c.4132T>G p.L1378V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); called by muse, varscan2
- DGCR2 | c.203-1G>T p.X68_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- DGKK | c.2182A>T p.T728S | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DUSP26 | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DYNC1H1 | c.12910del p.E4304Sfs*36 | Frame Shift Del (DEL) | VAF 18/161 reads (11%) | called by mutect2, pindel, varscan2
- EFCAB6 | c.4400G>T p.S1467I | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- EFR3A | c.1904T>A p.F635Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FZD2 | c.1421C>A p.T474N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GMIP | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GPNMB | c.1096G>T p.D366Y (on ENST00000381990 / NM_001005340.2; = p.D354Y on NM_002510.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GPX3 | c.440A>T p.K147I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- HPS6 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- KIAA1549L | c.4454C>T p.T1485I (on ENST00000321505; = p.T1782I on NM_012194.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4A | c.2846A>G p.E949G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LRP2 | c.1543A>C p.I515L | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP2 | c.2425dup p.M809Nfs*19 | Frame Shift Ins (INS) | VAF 18/179 reads (10%) | called by mutect2, pindel
- MAST1 | c.815C>G p.T272S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MRGPRX3 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2
- NT5C3B | c.791A>T p.Y264F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- PPP1R12B | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG7 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- RTN4 | c.3215C>T p.P1072L (on ENST00000337526 / NM_020532.5; = p.P79L on NM_007008.3) | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RWDD2A | c.69del p.P24Lfs*6 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- SLC23A3 | c.1727A>T p.D576V (on ENST00000409878 / NM_001144889.2; = p.D459V on NM_144712.5) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SLC38A8 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.345); called by muse, mutect2
- SLC5A6 | c.479T>A p.V160E | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SLCO1C1 | c.959A>G p.D320G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- THAP4 | c.815G>C p.S272T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, varscan2
- TMIGD1 | c.596C>G p.S199* | Nonsense Mutation (SNP) | VAF 14/309 reads (5%) | called by muse, mutect2
- TMPRSS11F | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ZNF638 | c.5935_*5del | Nonstop Mutation (DEL) | VAF 16/98 reads (16%) | called by mutect2, varscan2
- ZNF708 | c.145A>T p.N49Y | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, varscan2
- ZNF79 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC244197.3 | c.999T>G p.L333= | Silent (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- ADD2 | c.696C>A p.A232= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV52466346; called by muse, mutect2
- AKAP1 | c.1089G>T p.V363= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- ALOXE3 | c.1983G>A p.E661= | Silent (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- CCNB2 | c.894T>C p.Y298= | Silent (SNP) | VAF 16/382 reads (4%) | catalogued as rs1262481143; called by muse, mutect2
- EIF3J | c.687A>T p.G229= | Silent (SNP) | VAF 85/353 reads (24%) | called by muse, mutect2, varscan2
- ERBIN | c.3576T>A p.V1192= | Silent (SNP) | VAF 59/145 reads (41%) | called by muse, mutect2, varscan2
- HNRNPUL2 | c.690G>T p.L230= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as COSV53665611; called by muse, mutect2, varscan2
- IPO5 | c.2937C>A p.I979= | Silent (SNP) | VAF 48/184 reads (26%) | catalogued as COSV55160814; called by muse, mutect2, varscan2
- MCM8 | c.222A>C p.P74= | Silent (SNP) | VAF 17/183 reads (9%) | called by muse, mutect2, varscan2
- NECTIN3 | c.1482G>A p.Q494= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as rs780858409; called by muse, varscan2
- NKAPL | c.369G>A p.K123= | Silent (SNP) | VAF 62/182 reads (34%) | called by muse, mutect2, varscan2
- OR10J5 | c.273T>C p.P91= | Silent (SNP) | VAF 141/366 reads (39%) | catalogued as rs751473571; called by muse, mutect2, varscan2
- PLCB1 | c.1536C>T p.D512= | Silent (SNP) | VAF 38/219 reads (17%) | catalogued as rs544749418; called by muse, mutect2, varscan2
- RBBP4 | c.1143C>T p.S381= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1322618196; called by muse, mutect2, varscan2
- SLC23A2 | c.714A>C p.L238= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV57777538; called by muse, mutect2, varscan2
- TDRD6 | c.2541C>G p.V847= | Silent (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.1383T>A p.G461= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- ZNF670 | c.1005A>G p.K335= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs975387651; called by muse, mutect2, varscan2
- DCHS2 | n.7104C>A | RNA (SNP) | VAF 18/180 reads (10%) | catalogued as COSV100602559; called by muse, mutect2
